Somatic mutation profile of tumor specimen TCGA-AR-A1AT-01A (aliquot TCGA-AR-A1AT-01A-11D-A12Q-09) from TCGA case TCGA-AR-A1AT, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.8 years (22,942 days).
Specimen TCGA-AR-A1AT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d5a44d3-a7dd-4d02-8e53-1868e0dacd81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A1AT-10A (Blood Derived Normal), aliquot TCGA-AR-A1AT-10A-01D-A12Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5008b526-898d-4d58-879d-51d4819dae69

The open-access MAF lists 29 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 18, Silent 6, Frame Shift Del 4, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC42BPG | c.4645A>C p.S1549R | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as rs768145719, COSV61349589; called by muse, mutect2, varscan2
- EPS15 | c.1931G>T p.G644V | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV65545802; called by muse, mutect2, varscan2
- FAM214A | c.1531C>G p.H511D | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV55927693; called by muse, mutect2, varscan2
- FOXK1 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1042693899, COSV61069261; called by muse, mutect2, varscan2
- MYH9 | c.3060del p.K1020Nfs*9 | Frame Shift Del (DEL) | VAF 68/302 reads (23%) | catalogued as COSV53394365; called by mutect2, pindel, varscan2
- PLCB2 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV53038833; called by muse, mutect2, varscan2
- PSMD3 | c.601C>G p.R201G | Missense Mutation (SNP) | VAF 29/505 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99227676; called by muse, mutect2
- PUS7L | c.1570C>T p.H524Y | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV61262854, COSV61263115; called by muse, mutect2, varscan2
- RFPL1 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.779); catalogued as rs769214763, COSV62978749; called by muse, mutect2, varscan2
- RXFP3 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV57505571; called by muse, mutect2, varscan2
- SKOR1 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1196630683, COSV58250257; called by muse, mutect2, varscan2
- SNX16 | c.375+1del p.X125_splice | Splice Site (DEL) | VAF 16/134 reads (12%) | catalogued as rs757355533, COSV62036998; called by mutect2, varscan2
- SP140 | c.998A>G p.E333G | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1361805196, COSV100613563; called by muse, mutect2, varscan2
- SPTY2D1 | c.265A>G p.T89A | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60475822; called by muse, mutect2, varscan2
- STARD7 | c.354G>C p.Q118H | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV61527006; called by muse, mutect2, varscan2
- TBC1D22B | c.523G>C p.A175P | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs778955950, COSV65142275, COSV65142509; called by mutect2, varscan2
- TDRD9 | c.2824C>T p.P942S | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as COSV59157724; called by muse, mutect2, varscan2
- TTN | c.19022C>G p.T6341S (on ENST00000591111; = p.T5414S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | PolyPhen benign (0.01); catalogued as COSV60398467; called by muse, mutect2, varscan2
- ZNF239 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs113213479, COSV100021959, COSV60019988; called by muse, mutect2
- ZNF296 | c.1309G>T p.G437C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55519891; called by muse, mutect2, varscan2
- CDH1 | c.944del p.N315Ifs*41 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | called by mutect2, pindel, varscan2
- RUNX1 | c.253del p.L85Cfs*10 (on ENST00000344691 / NM_001001890.3; = p.L112Cfs*10 on NM_001754.5) | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- SERPINA1 | c.849del p.K283Nfs*41 | Frame Shift Del (DEL) | VAF 39/156 reads (25%) | called by mutect2, pindel, varscan2
- AC144573.1 | c.828C>T p.L276= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV56878076; called by muse, mutect2, varscan2
- DNTT | c.1134C>T p.D378= | Silent (SNP) | VAF 49/140 reads (35%) | catalogued as COSV64523820; called by muse, mutect2, varscan2
- KMT2A | c.4101G>A p.P1367= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as rs781789464, COSV100629944, COSV63293501; called by muse, mutect2, varscan2
- MAMDC2 | c.525T>C p.N175= | Silent (SNP) | VAF 41/160 reads (26%) | catalogued as COSV65861219; called by muse, mutect2, varscan2
- MUC16 | c.6297T>C p.S2099= | Silent (SNP) | VAF 25/119 reads (21%) | catalogued as COSV67499986; called by muse, mutect2, varscan2
- TNRC6A | c.1125C>T p.N375= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV59370970; called by muse, mutect2, varscan2
